Somatic mutation profile of tumor specimen MMRF_2465_1_BM_CD138pos (aliquot MMRF_2465_1_BM_CD138pos_T1_KHS5U_K15200) from MMRF case MMRF_2465, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,570 days).
Specimen MMRF_2465_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9332706d-5cfb-4084-821e-6c06366cb408.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2465_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2465_1_PB_WBC_C3_KHS5U_K15201; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0650b2e5-d446-47a4-8cfd-e308bc6ad53d

The open-access MAF lists 118 somatic variants for this specimen: 50 protein-altering or splice-affecting, 16 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 27, Silent 16, Intron 14, Nonsense Mutation 5, RNA 4, 5'UTR 3, Splice Site 3, 5'Flank 3, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 54/249 reads (22%) | catalogued as rs758555274, COSV56443963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.3046C>T p.R1016* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as rs759085500, COSV100617298; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD55 | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 25/97 reads (26%) | catalogued as COSV61946060; called by muse, mutect2, varscan2
- COL6A1 | c.2986G>A p.V996M | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs764765574, COSV62613222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCC | c.3167G>A p.R1056H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs200519902; called by muse, mutect2, varscan2
- FAM135B | c.4139G>A p.R1380Q | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs997576188, COSV52719126; called by muse, mutect2
- IGHV1-69D | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- IGHV2-70 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as rs10144402; called by muse, varscan2
- IGKV1-5 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs565198349; called by muse, varscan2
- IGLV3-1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as rs545664491; called by muse, mutect2, varscan2
- LILRA1 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV52178843; called by muse, varscan2
- LRRC15 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs552954426, COSV61652061; called by muse, mutect2, varscan2
- MED12L | c.4699A>G p.T1567A | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV56368536; called by muse, mutect2, varscan2
- MYO7B | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs765869041, COSV101267815, COSV67348734; called by muse, mutect2, varscan2
- NANOGNB | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1249603000, COSV99062963; called by muse, mutect2
- SPOCK3 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs772362822; called by muse, mutect2, varscan2
- TENT5C | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65616320; called by muse, varscan2
- TSPAN10 | c.566G>A p.R189H (on ENST00000574882 / NM_001290212.1; = p.R151H on NM_031945.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs533267022; called by muse, mutect2
- UGT2B7 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs754330234, COSV59443351; called by muse, mutect2, varscan2
- ARPC5 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 14/373 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.345); called by muse, mutect2
- BMP5 | c.922A>G p.S308G | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- C8orf34 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 71/379 reads (19%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- CADM4 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC105 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC180 | c.2491A>T p.K831* | Nonsense Mutation (SNP) | VAF 51/149 reads (34%) | called by muse, mutect2, varscan2
- CLGN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- FAT4 | c.13939C>A p.H4647N | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FBXO34 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GMDS | c.235A>C p.N79H | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); called by mutect2, varscan2
- HDAC1 | c.1055dup p.N352Kfs*6 | Frame Shift Ins (INS) | VAF 25/159 reads (16%) | called by mutect2, pindel, varscan2
- HTRA1 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 77/301 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV5-2 | c.48T>C p.S16= | Splice Region (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- KATNB1 | c.295del p.R99Afs*22 | Frame Shift Del (DEL) | VAF 21/150 reads (14%) | called by mutect2, pindel, varscan2
- LRRFIP2 | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEMF | c.2895+2T>A p.X965_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- NONO | c.529G>C p.A177P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NPAS4 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- NR2F2 | c.1091T>C p.L364S | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCED1B | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 81/390 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PJA2 | c.1727A>G p.Y576C | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP4R3B | c.1201T>C p.F401L | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PPP5C | c.1176+2dup p.X392_splice | Splice Site (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel
- PRR32 | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOGA1 | c.1448A>G p.D483G | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENM2 | c.1657T>G p.F553V (on ENST00000518659 / NM_001122679.2; = p.F321V on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.871); called by muse, mutect2
- TENT5C | c.812G>C p.C271S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, varscan2
- TLE1 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- UHRF1BP1L | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF320 | c.366T>A p.S122R | Missense Mutation (SNP) | VAF 122/391 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ADAMTS5 | c.1326C>T p.I442= | Silent (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- ADGRA1 | c.1449G>A p.Q483= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- C10orf90 | c.1395T>C p.L465= | Silent (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- C2orf16 | c.4626C>T p.P1542= | Silent (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- CFH | c.582C>T p.D194= | Silent (SNP) | VAF 32/202 reads (16%) | catalogued as rs573136624, COSV62778475; called by muse, mutect2, varscan2
- COL4A1 | c.2118C>T p.D706= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- ERN2 | c.1656C>T p.R552= | Silent (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- FLNA | c.1554C>T p.T518= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs1557178984; ClinVar: likely benign; called by muse, mutect2, varscan2
- GGACT | c.123G>A p.P41= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs373993016; called by muse, mutect2, varscan2
- OR5A1 | c.681G>A p.A227= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as rs370559050, COSV57378879; called by muse, mutect2, varscan2
- P2RY4 | c.123C>T p.S41= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs1247335543; called by muse, mutect2, varscan2
- PHF21B | c.1509C>T p.S503= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs1363396750; called by muse, mutect2, varscan2
- PHGR1 | c.129C>T p.C43= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs928164405, COSV51130411; called by muse, varscan2
- RBMXL3 | c.3174C>T p.F1058= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs782372947; called by muse, mutect2, varscan2
- SLC44A4 | c.765G>A p.G255= | Silent (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- SYCE1L | c.36G>A p.A12= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs1342674159, COSV99941794; called by muse, mutect2, varscan2
- AARD | c.*740C>T | 3'UTR (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- AKAP13 | c.478+3012G>A | Intron (SNP) | VAF 6/69 reads (9%) | catalogued as rs1300543677; called by muse, mutect2
- ANKRD42 | c.*28A>T | 3'UTR (SNP) | VAF 46/302 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502436 A>G | 5'Flank (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.-82G>A | 5'UTR (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- ARPC4 | c.*389G>A | 3'UTR (SNP) | VAF 14/71 reads (20%) | catalogued as rs1336104588; called by muse, mutect2, varscan2
- ATP8A1 | c.*2053C>T | 3'UTR (SNP) | VAF 8/41 reads (20%) | catalogued as rs927058993; called by muse, mutect2, varscan2
- BARHL2 | c.*117G>A | 3'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021699 G>C | 5'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- BLCAP | c.*703C>T | 3'UTR (SNP) | VAF 14/69 reads (20%) | catalogued as rs1026248298; called by muse, mutect2, varscan2
- CCSER1 | c.2011-34218T>G | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- CEP126 | c.*1054G>T | 3'UTR (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- CHTF8 | chr16:69118592 C>T | 3'Flank (SNP) | VAF 6/140 reads (4%) | catalogued as rs1264963926; called by muse, mutect2
- CKAP2 | c.*1004T>A | 3'UTR (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- CLIC4 | c.*1718C>A | 3'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- DHFR2 | c.*2975G>A | 3'UTR (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
- DPP10 | c.*2985T>G | 3'UTR (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- DPP4 | c.-40G>C | 5'UTR (SNP) | VAF 15/120 reads (13%) | catalogued as rs1213940748, COSV100858800; called by muse, mutect2, varscan2
- DUT | c.*1021C>T | 3'UTR (SNP) | VAF 13/122 reads (11%) | catalogued as rs914691909; called by muse, mutect2, varscan2
- FAM107B | c.*265A>G | 3'UTR (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- FBXO48 | c.*1218A>G | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- HSPB8 | c.-366C>T | 5'UTR (SNP) | VAF 23/129 reads (18%) | catalogued as rs1002861107; called by muse, mutect2, varscan2
- IFI44 | c.691-58T>G | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- IL1R1 | c.*3020T>G | 3'UTR (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- IMP3 | c.*2G>T | 3'UTR (SNP) | VAF 83/265 reads (31%) | catalogued as rs1350403049, COSV100145754; called by muse, mutect2, varscan2
- MIR663A | n.34C>A | RNA (SNP) | VAF 12/80 reads (15%) | catalogued as rs746163362; called by muse, mutect2, varscan2
- NAMPTP1 | n.82T>C | RNA (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- NPTXR | c.*2055C>T | 3'UTR (SNP) | VAF 14/139 reads (10%) | catalogued as rs867199516; called by muse, mutect2, varscan2
- NR5A2 | c.1110+9340G>A | Intron (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- NRXN1 | c.*1140A>C | 3'UTR (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- PCDH7 | c.*277C>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as rs75387584; called by muse, varscan2
- PELATON | n.311A>G | RNA (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- PKHD1 | c.*1026C>T | 3'UTR (SNP) | VAF 12/62 reads (19%) | catalogued as rs745560749; called by muse, mutect2, varscan2
- PPARGC1A | c.804-25T>G | Intron (SNP) | VAF 48/198 reads (24%) | called by muse, mutect2, varscan2
- PPFIA2 | c.303+78452G>C | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as rs988236218; called by muse, mutect2, varscan2
- PSMD2 | c.1451+42A>G | Intron (SNP) | VAF 29/154 reads (19%) | called by muse, mutect2, varscan2
- QPCT | c.*175T>C | 3'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- RASA1 | c.2344+38G>C | Intron (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- REV1 | c.2615-104T>A | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- RNF144B | c.*2341_*2342insGT | 3'UTR (INS) | VAF 5/32 reads (16%) | catalogued as rs1002017572; called by pindel, varscan2
- SATL1 | chrX:85108995 T>C | 5'Flank (SNP) | VAF 35/141 reads (25%) | called by muse, mutect2, varscan2
- SERPINA3 | c.644-631A>T | Intron (SNP) | VAF 24/160 reads (15%) | called by muse, mutect2, varscan2
- STK17A | c.*1234A>T | 3'UTR (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- STRADA | c.859-386C>G | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- STRC | c.3372+93C>A | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- TENT5A | c.*481A>G | 3'UTR (SNP) | VAF 3/38 reads (8%) | catalogued as rs1030630706; called by muse, mutect2
- TIMM17A | c.*61A>C | 3'UTR (SNP) | VAF 67/325 reads (21%) | called by muse, mutect2, varscan2
- TMCC1 | c.*3523_*3524del | 3'UTR (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- TMEM141 | c.122-10C>T | Intron (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- TPRX2P | n.291G>A | RNA (SNP) | VAF 18/101 reads (18%) | catalogued as rs749296712; called by mutect2, varscan2
- VPS4A | c.769+53C>A | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2
- ZNF385D | c.*2291T>C | 3'UTR (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
